Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7075, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7075-01A (Primary Tumor).

CGA-HC-7075

Collected:
Received:
Reported:

Accession #
Acct / Reg #

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Prostate, radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 6 x 5.5 x 4 cm, 41 grams.
3. Tumor quantitation: Tumor occupies approximately 25% of the anterior portion of the right lobe of the prostate.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 6/10.
5. Extraprostatic extension: No.
6. Seminal vesicle involvement: No.
7. Lymphovascular space invasion: No.
8. High grade PIN: Present.

Surgical Margin Status:

1. All margins of excision are free of carcinoma.

Other:

1. pTNM stage: pT2aNXMX

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm prostate.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Prostate.

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received labeled with the patient's name and prostate. The specimen consists of an intact prostate measuring 6 x 5.5 x 4 cm and weighs 41 grams. The surface of the prostate is gray to brown-tan with slight adhesions. The right half has been inked black and the left half has been inked blue. The attached seminal vesicles measure on average 3.5 cm in length and 1 cm in diameter, and are grossly unremarkable. The vas deferens measure 5 cm in length and 0.2 cm in diameter, and grossly unremarkable. The prostate is serially sectioned from apex to base and reveals a gray-tan, rubbery, nodular cut surface. Definitive mass is not grossly identified. Received with the specimen are 2 cassettes; 1 green and 1 yellow labeled. Representative sections are submitted in cassettes labeled as follows: right seminal vesicle and vas block 1; left seminal vesicle and vas block 2; perpendicular sections taken from margins from block 3, base block 4; prostate submitted from apex to base as follows: level 1: left anterior block 5; left posterior block 6; right posterior block 7; right anterior block 8; level 2: left anterior block 9; left posterior block 10; right posterior block 11; right anterior block 12; level 3: left anterior block 13; left posterior block 14; right posterior block 15; right anterior block 16.

Source: NCI Genomic Data Commons file 46bf13da-e86c-4f78-a234-1d54d3fbd3ed (TCGA-HC-7075.72E3166C-BBD4-4BC1-931C-5FDA225B3CF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).